MMRF case MMRF_2062 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e46ceb7d-7eda-451b-8f3d-07ea4768db91

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.9 years (22,978 days); ISS stage: III; Days to last known disease status: 636 days (1.7 years); Days to last follow up: 636 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 472 days (1.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 636.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 580 mg/dL; Beta 2 Microglobulin 7.7 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 18 ×10⁹/L; Creatinine 294 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 3.15 mmol/L; Albumin 30 g/L; Total Protein 6.4 g/dL; Glucose 4.51 mmol/L.
- Day 99 (ECOG 0): Hemoglobin 6.88 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 33 g/L; Total Protein 7.2 g/dL; Glucose 4.62 mmol/L.
- Day 162 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Hemoglobin 6.82 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 7 g/dL; Glucose 5.28 mmol/L.
- Day 258 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.04 mg/dL; Immunoglobulin G 21.1 g/L; Immunoglobulin A 2.78 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 32 g/L; Total Protein 7 g/dL; Glucose 5.34 mmol/L.

Other clinical attributes
- Day 0: Weight: 99 kg; Height: 183 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2062_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2062_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
